Somatic mutation profile of tumor specimen MBCProject_0419_T1_WES (aliquot MBCProject_0419_T1_WES_1) from CMI case MBCProject_0419, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 36.4 years (13,306 days).
Specimen MBCProject_0419_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75ced04d-ebc7-431b-866a-60c764847f64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0419_SALIVA (Saliva), aliquot MBCProject_0419_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bc43d3a-4ef3-4d42-aecd-1f19ce59847f

The open-access MAF lists 49 somatic variants for this specimen: 29 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 13, Intron 3, Nonsense Mutation 2, Splice Region 1, 3'UTR 1, RNA 1, 3'Flank 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 25/92 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- IKBKB | c.809C>G p.A270G | Missense Mutation (SNP) | VAF 30/339 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV104416122; called by muse, mutect2
- ITLN1 | c.833A>T p.Q278L | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV58276354; called by muse, mutect2, varscan2
- NPC1L1 | c.4069C>T p.R1357W | Missense Mutation (SNP) | VAF 68/474 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs755084966; called by muse, mutect2, varscan2
- OR10A4 | c.296C>G p.A99G | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV65842423; called by muse, mutect2, varscan2
- PCDHA6 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 70/502 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV65343372; called by muse, mutect2, varscan2
- PLK1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 105/388 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55625221; called by muse, mutect2, varscan2
- SHISA6 | c.1072C>T p.R358* (on ENST00000409168 / NM_001173461.1; = p.R409* on NM_207386.4) | Nonsense Mutation (SNP) | VAF 13/147 reads (9%) | catalogued as COSV69385996; called by muse, mutect2
- SKAP1 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV100412408; called by muse, mutect2, varscan2
- ZNF682 | c.998G>C p.R333T | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.59); catalogued as rs761167607; called by muse, mutect2, varscan2
- ADAMTSL2 | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- BACH2 | c.142T>A p.F48I | Missense Mutation (SNP) | VAF 103/392 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- BICRA | c.1245_1249delinsG p.A416Lfs*27 | Frame Shift Del (DEL) | VAF 37/252 reads (15%) | called by pindel, varscan2*
- CHAD | c.214C>G p.R72G | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP4 | c.3691C>T p.P1231S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOK4 | c.860C>G p.A287G | Missense Mutation (SNP) | VAF 90/365 reads (25%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- FKTN | c.1102T>G p.F368V | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GCC2 | c.1999G>T p.E667* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2, varscan2
- GOLGB1 | c.96+8G>A | Splice Region (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2
- HSPA9 | c.1336G>T p.G446C | Missense Mutation (SNP) | VAF 60/421 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF24 | c.3122A>T p.H1041L | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC5B | c.5405G>A p.G1802E | Missense Mutation (SNP) | VAF 104/644 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- OGDHL | c.2602C>G p.Q868E | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by mutect2, varscan2
- PCDH7 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 206/547 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGB1 | c.1964C>T p.T655M | Missense Mutation (SNP) | VAF 186/532 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- PCOLCE | c.571A>G p.I191V | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TLE1 | c.1909G>C p.D637H | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC30B | c.1118A>G p.E373G | Missense Mutation (SNP) | VAF 77/239 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- XKR4 | c.1171G>C p.A391P | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS7 | c.2310C>T p.Y770= | Silent (SNP) | VAF 66/408 reads (16%) | catalogued as rs760730710, COSV66306608; called by muse, mutect2, varscan2
- CD55 | c.69G>A p.L23= | Silent (SNP) | VAF 123/422 reads (29%) | catalogued as rs1327488422; called by muse, mutect2, varscan2
- DENND4A | c.5058T>C p.S1686= | Silent (SNP) | VAF 7/132 reads (5%) | called by muse, mutect2
- EVX1 | c.261T>C p.A87= | Silent (SNP) | VAF 54/348 reads (16%) | called by muse, mutect2, varscan2
- IL37 | c.396C>T p.S132= | Silent (SNP) | VAF 20/207 reads (10%) | catalogued as rs1470859462, COSV54493463; called by muse, mutect2
- INHA | c.180A>T p.R60= | Silent (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- PASK | c.915C>T p.D305= | Silent (SNP) | VAF 120/415 reads (29%) | catalogued as rs779444106; called by muse, mutect2, varscan2
- PCDHA6 | c.2202G>A p.A734= | Silent (SNP) | VAF 67/403 reads (17%) | catalogued as rs782325255, COSV65343043; called by muse, mutect2, varscan2
- PITX1 | c.891C>T p.Y297= | Silent (SNP) | VAF 48/248 reads (19%) | catalogued as rs1178354724; called by muse, mutect2
- SPOCD1 | c.1191C>T p.L397= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs200509383; called by muse, mutect2, varscan2
- TBC1D12 | c.330G>A p.L110= | Silent (SNP) | VAF 111/296 reads (38%) | called by muse, mutect2, varscan2
- TTC28 | c.6900C>T p.S2300= | Silent (SNP) | VAF 46/89 reads (52%) | called by muse, mutect2, varscan2
- UTS2 | c.120G>A p.A40= | Silent (SNP) | VAF 25/175 reads (14%) | catalogued as rs759501467, COSV50013627; called by muse, mutect2, varscan2
- ALDOA | c.1162-17C>A | Intron (SNP) | VAF 86/474 reads (18%) | called by muse, mutect2, varscan2
- EDRF1 | c.2371+161A>G | Intron (SNP) | VAF 8/100 reads (8%) | catalogued as rs1299179669; called by muse, mutect2
- FMN2 | c.4066-12413G>T | Intron (SNP) | VAF 31/128 reads (24%) | catalogued as COSV60452506; called by muse, mutect2, varscan2
- GVINP1 | n.3338C>T | RNA (SNP) | VAF 38/162 reads (23%) | catalogued as rs755490559; called by muse, mutect2, varscan2
- MOCS1 | c.*1267_*1268dup | 3'UTR (INS) | VAF 151/292 reads (52%) | called by mutect2, pindel, varscan2
- PIP4K2B | c.-17C>T | 5'UTR (SNP) | VAF 37/1379 reads (3%) | called by muse, mutect2
- SNAPC5 | chr15:66490457 T>C | 3'Flank (SNP) | VAF 87/514 reads (17%) | catalogued as rs767106355; called by muse, mutect2, varscan2
